Somatic mutation profile of tumor specimen TCGA-KK-A7AW-01A (aliquot TCGA-KK-A7AW-01A-11D-A32B-08) from TCGA case TCGA-KK-A7AW, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 57.1 years (20,869 days).
Specimen TCGA-KK-A7AW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4a1aef94-5671-486d-9a0c-bee68626d6b9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KK-A7AW-11A (Solid Tissue Normal), aliquot TCGA-KK-A7AW-11A-11D-A329-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/09f3f28b-3229-4c08-b71f-cc5d6cdfafc8

The open-access MAF lists 30 somatic variants for this specimen: 20 protein-altering or splice-affecting, 8 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 8, Splice Site 2, Nonsense Mutation 1, Intron 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AMDHD1 | c.512G>A p.R171H | Missense Mutation (SNP) | VAF 23/114 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.059); catalogued as COSV57138267; called by muse, mutect2, varscan2
- C10orf99 | c.106A>G p.R36G | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.141); catalogued as COSV100929373; called by muse, mutect2, varscan2
- CSF2RA | c.458A>C p.Y153S | Missense Mutation (SNP) | VAF 9/114 reads (8%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.754); catalogued as COSV100817886, COSV100817966; called by muse, mutect2
- DMRT2 | c.628G>C p.G210R (on ENST00000358146 / NM_001370532.1; = p.V210L on NM_006557.7 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99426263; called by muse, mutect2
- EEF2K | c.408+1G>T p.X136_splice | Splice Site (SNP) | VAF 7/42 reads (17%) | catalogued as COSV99533707; called by muse, mutect2, varscan2
- HIC2 | c.1342G>A p.A448T | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); catalogued as rs770298758, COSV101335640; called by muse, mutect2, varscan2
- KIAA1109 | c.7696C>T p.H2566Y | Missense Mutation (SNP) | VAF 79/263 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.265); catalogued as COSV99176609; called by muse, mutect2, varscan2
- MBTPS1 | c.2962+1G>T p.X988_splice | Splice Site (SNP) | VAF 12/58 reads (21%) | catalogued as COSV100597824; called by muse, mutect2, varscan2
- NEURL3 | c.469G>A p.A157T | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100182502; called by muse, mutect2, varscan2
- NMUR2 | c.545C>A p.T182N | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV99677342; called by muse, mutect2, varscan2
- PCDHA9 | c.1883C>T p.T628M | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.819); catalogued as rs1365314674, COSV100969448; called by muse, mutect2, varscan2
- PKHD1 | c.10445G>A p.R3482H | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as rs143915416; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RALGDS | c.1150G>T p.V384L | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as COSV100924567; called by muse, mutect2, varscan2
- RLIM | c.1802T>C p.L601S | Missense Mutation (SNP) | VAF 50/57 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100223326; called by muse, mutect2, varscan2
- TIAM2 | c.2671G>A p.V891M | Missense Mutation (SNP) | VAF 34/162 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.822); catalogued as rs756880652, COSV59695226; called by muse, mutect2, varscan2
- TMEM209 | c.488G>T p.S163I | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100390643; called by muse, mutect2, varscan2
- TRPA1 | c.1027C>T p.R343C | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.967); catalogued as rs372548303, COSV51566060; called by muse, mutect2, varscan2
- USH2A | c.6197C>T p.S2066F | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); catalogued as COSV100242962; called by muse, mutect2, varscan2
- USP24 | c.4960A>C p.I1654L | Missense Mutation (SNP) | VAF 17/25 reads (68%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV99600978; called by muse, mutect2, varscan2
- VPS50 | c.706C>T p.Q236* | Nonsense Mutation (SNP) | VAF 4/41 reads (10%) | catalogued as COSV99298521; called by muse, mutect2
- BMPR2 | c.1773A>T p.R591= | Silent (SNP) | VAF 9/65 reads (14%) | catalogued as COSV101001537, COSV101001667, COSV65808773; called by muse, mutect2, varscan2
- CACNA1G | c.873C>T p.D291= | Silent (SNP) | VAF 6/12 reads (50%) | catalogued as rs751467172, COSV61722990; called by muse, mutect2, varscan2
- COL4A3 | c.825C>G p.P275= | Silent (SNP) | VAF 6/64 reads (9%) | catalogued as COSV101170541; called by muse, mutect2
- PDPR | c.693G>A p.Q231= | Silent (SNP) | VAF 6/54 reads (11%) | catalogued as COSV99848907; called by muse, varscan2
- SI | c.3219C>T p.G1073= | Silent (SNP) | VAF 59/178 reads (33%) | catalogued as COSV100017244; called by muse, mutect2, varscan2
- SNTG2 | c.1206C>T p.N402= | Silent (SNP) | VAF 3/20 reads (15%) | catalogued as rs371202003; called by muse, mutect2
- STK32B | c.1212C>T p.L404= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as rs1186260977, COSV99287461; called by muse, mutect2, varscan2
- SYNE1 | c.11784C>T p.N3928= | Silent (SNP) | VAF 9/61 reads (15%) | catalogued as COSV99579452; called by muse, mutect2, varscan2
- GRIA4 | c.2544+39G>A | Intron (SNP) | VAF 11/69 reads (16%) | catalogued as rs775396396, COSV56918132; called by muse, mutect2, varscan2
- SNORD108 | n.18A>G | RNA (SNP) | VAF 11/58 reads (19%) | called by mutect2, varscan2
